Gene-level copy-number profile of tumor specimen TARGET-10-PARMRF-09A from TARGET case TARGET-10-PARMRF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,186 days).
Specimen TARGET-10-PARMRF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.e240ebbc-831c-527c-9a66-2cb6b02acb28.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PARMRF-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 394 have no estimate.
https://portal.gdc.cancer.gov/files/0cbbc151-209f-407f-80b3-592889914894

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 2,414; copy number 2: 57,580; copy number 3: 22; copy number 4: 125; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 87 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,291,616–38,318,861, 5 genes (within-gene range 0–1): TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr7:142,389,202–142,802,748, 69 genes (broad region; genes not listed).
- chr9:21,802,636–22,029,594, 8 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr17:41,271,311–41,271,835, 1 gene: KRTAP9-11P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:133,430,394–133,431,318, 1 gene, copy number 5: OR6L2P.

Autosomal genes at a single copy (total copy number 1): 33. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
